Somatic mutation profile of tumor specimen TARGET-15-SJMPAL011915-09A (aliquot TARGET-15-SJMPAL011915-09A-01D) from TARGET case TARGET-15-SJMPAL011915, project TARGET-ALL-P3 (Acute Lymphoblastic Leukemia - Phase III). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.7 years (990 days).
Specimen TARGET-15-SJMPAL011915-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a196f9bb-3af8-44c0-ab73-a6e0a0b9b9ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-15-SJMPAL011915-14A (Bone Marrow Normal), aliquot TARGET-15-SJMPAL011915-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/04ce16d8-8c62-4292-893d-19f874c4d683

The open-access MAF lists 17 somatic variants for this specimen: 12 protein-altering or splice-affecting, 1 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 11, Intron 2, 5'Flank 1, Silent 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EPHB4 | c.916G>A p.V306I | Missense Mutation (SNP) | VAF 10/38 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs780811289; called by mutect2, varscan2
- GLIS3 | c.323G>T p.G108V | Missense Mutation (SNP) | VAF 3/34 reads (9%) | SIFT tolerated (0.28); PolyPhen benign (0.033); catalogued as rs1020349405, COSV101127555; called by muse, mutect2
- OPRL1 | c.308C>A p.T103K | Missense Mutation (SNP) | VAF 6/70 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100402206; called by muse, mutect2
- WT1 | c.1091_1092insCG p.T365Gfs*73 | Frame Shift Ins (INS) | VAF 47/129 reads (36%) | catalogued as COSV100187393, COSV60065578, COSV60066574, COSV60067966, COSV60069180, COSV60069294, COSV60069675, COSV60071329, COSV60072717, COSV60072799, COSV60073173, COSV60073318, COSV60074036, COSV60082207, COSV60083929, COSV…; called by pindel, varscan2
- ALX1 | c.203C>A p.T68N | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.012); called by muse, mutect2
- ANKRD35 | c.2057C>A p.A686D | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2
- ANXA11 | c.1337G>T p.G446V | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- HR | c.1535G>T p.C512F | Missense Mutation (SNP) | VAF 4/44 reads (9%) | SIFT deleterious (0.03); PolyPhen benign (0.005); called by muse, mutect2
- OR2J3 | c.443C>A p.A148D | Missense Mutation (SNP) | VAF 8/80 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- RAPGEF3 | c.517G>T p.A173S (on ENST00000389212; = p.A131S on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.43); PolyPhen benign (0.056); called by muse, mutect2
- RFX2 | c.910G>T p.A304S | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- TTBK2 | c.2048G>T p.S683I | Missense Mutation (SNP) | VAF 4/32 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.852); called by muse, varscan2
- PCDHGA3 | c.1611C>T p.S537= | Silent (SNP) | VAF 57/178 reads (32%) | catalogued as COSV53954039; called by muse, mutect2, varscan2
- METAP1 | chr4:98995714 C>T | 5'Flank (SNP) | VAF 6/16 reads (38%) | called by muse, mutect2, varscan2
- PPIL4 | c.-9G>T | 5'UTR (SNP) | VAF 4/48 reads (8%) | called by muse, mutect2
- TRAPPC2L | c.374+150C>A | Intron (SNP) | VAF 5/42 reads (12%) | called by muse, mutect2, varscan2
- ZFHX3 | c.-1546-30543G>A | Intron (SNP) | VAF 24/54 reads (44%) | catalogued as rs745949631; called by muse, varscan2
